TARGET case TARGET-10-PALKTY — Acute Lymphoblastic Leukemia - Phase I (TARGET-ALL-P1)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6c32a0e9-8d6d-492f-a6f9-46bbe9962016

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Age at index: 6 years; Vital status: Dead; Days to death: 1,507 days (4.1 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 6.1 years (2,223 days); Year of diagnosis: 2002; Days to last follow up: 1,507 days (4.1 years).
   Treatment given: Protocol identifier: P9906.

Follow-up (2 entries)
- Days to follow up: 1,310 days (3.6 years); Days to first event: 1,310 days (3.6 years); First event: Relapse.
- Days to follow up: 1,507 days (4.1 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Nervous system, NOS; Year of follow up: 2006.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 202 ×10³/µL.
- Day 8: Bone Marrow blast count 4%.
- Day 29: Bone Marrow blast count 2%; Minimal Residual Disease (Flow Cytometry) 0.0593%.
- Minimal Residual Disease (Flow Cytometry) 0%.

Other clinical attributes
- Day 0: Comorbidities: Down Syndrome; Risk factors: Down Syndrome.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 1507
- WBC at Diagnosis: 202
- CNS Status at Diagnosis: CNS 1
- MRD Day 29: 0.059293044
- MRD End Consolidation: 0
- MRD End Consolidation Sensitivity: 0.01
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: Yes
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 4
- BMA Blasts Day 29: 2
- Karyotype: 48,XX,+8,DER(14;21)(Q10;Q10)C,+21C,+21[5]/46,XX,DER(14;21)(Q10;Q10)C,+21C[10]
- Down Syndrome: Yes
- DNA Index: 1
- Cell of Origin: B precursor (Non-T, Non-B ALL)
- ALL Molecular Subtype: None of above

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Xenografts_20230727.xlsx:
- Protocol: 9906
- Cell of Origin: B Cell ALL
